Gene-level copy-number profile of tumor specimen TCGA-ZH-A8Y5-01A from TCGA case TCGA-ZH-A8Y5, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 69.2 years (25,268 days).
Specimen TCGA-ZH-A8Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.faf9311a-d952-4518-84bb-9a46aebd931c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZH-A8Y5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4dbfc307-820b-41e5-acc2-7f91feaa4ffc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 10,054; copy number 2: 39,982; copy number 3: 4,092; copy number 4: 664; copy number 5: 2,983; copy number 6: 1,098; copy number 7: 941.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZH-A8Y5-01A-11D-A416-01): tumor purity 0.89, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:85,202,849–85,239,474, 1 gene (within-gene range 0–1): AL357172.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,022 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:115,471,941–121,580,524, 144 genes, copy number 5 (broad region; genes not listed).
- chr1:145,095,974–248,919,946, 2,546 genes, copy number 5–7 (broad region; genes not listed).
- chr8:63,136,223–145,066,685, 1,281 genes, copy number 5–6 (broad region; genes not listed).
- chr9:28,863,626–43,045,120, 398 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–22,437,041, 618 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr14:40,630,006–41,149,309, 2 genes, copy number 5 (within-gene range 3–5): AL390800.1, LINC02315.
- chr14:44,924,324–48,228,216, 29 genes, copy number 5 (within-gene range 3–5): KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871, RPL10L, MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3, MIR548Y, LINC00648, AL121576.1, AL359212.1, AL512358.1.
- chr16:70,802,084–71,230,722, 4 genes, copy number 5 (within-gene range 2–5): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 7,633. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
